Gene-level copy-number profile of tumor specimen TCGA-VM-A8C8-01A from TCGA case TCGA-VM-A8C8, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 50.6 years (18,494 days).
Specimen TCGA-VM-A8C8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.440c3c67-9d1a-4423-adcb-c0d98fbace37.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VM-A8C8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 350 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/804c1908-3c73-4421-8c8f-5e2c3db0304f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1,299; copy number 1: 13,211; copy number 2: 41,692; copy number 3: 3,633; copy number 4: 402; copy number 5: 14; copy number 7: 22.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VM-A8C8-01A-11D-A36N-01): tumor purity 0.37, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 325 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:14,124,233–14,124,335, 1 gene: RNU6-1265P.
- chr3:193,241,128–198,222,513, 174 genes (broad region; genes not listed).
- chr6:30,451,139–30,494,194, 5 genes: AL662873.1, TMPOP1, SUCLA2P1, RANP1, HLA-E.
- chr6:41,228,339–41,239,626, 2 genes: TREML4, RNA5SP207.
- chr8:143,437,659–145,066,685, 115 genes (within-gene range 0–2) (broad region; genes not listed).
- chr11:4,954,772–4,955,713, 1 gene: OR51A2.
- chr12:103,746,315–104,350,307, 20 genes (within-gene range 0–1): AC025265.1, NT5DC3, AC012555.2, AC012555.1, TTC41P, HSP90B1, MIR3652, C12orf73, TDG, GLT8D2, AC078819.1, HCFC2, NFYB, RNA5SP370, LINC02385, AC089983.2, TXNRD1, AC089983.1, RPL18AP3, EID3.
- chr13:70,564,267–70,564,437, 1 gene: AL445264.1.
- chr13:110,456,396–110,463,287, 1 gene: COL4A2-AS2.
- chr16:55,760,566–55,793,960, 1 gene (within-gene range 0–2): CES1P1.
- chr16:86,081,409–86,089,526, 1 gene: AC135012.1.
- chr17:40,977,716–40,987,135, 1 gene (within-gene range 0–2): KRT40.
- chr18:80,034,389–80,050,651, 1 gene: RBFA.
- chr22:32,188,400–32,188,487, 1 gene: AL008723.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 36 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:112,148,742–113,616,958, 9 genes, copy number 7: RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053, AC107890.1, AC055788.2, AC055788.1, AC103993.1.
- chr8:118,620,498–120,056,201, 27 genes, copy number 5–7: SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2, MAL2-AS1, MIR548AZ, AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3, ENPP2, CYCSP23, RN7SKP153, TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1, DEPTOR, RNA5SP277, AC091563.1.

Autosomal genes at a single copy (total copy number 1): 12,220. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
